Gene-level copy-number profile of tumor specimen TCGA-QK-A6VC-01A from TCGA case TCGA-QK-A6VC, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.6 years (22,865 days).
Specimen TCGA-QK-A6VC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.08d36fc4-2b62-42d9-a0c6-07da6145b132.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QK-A6VC-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7464259b-ad8d-4047-8871-aff4aba41db8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 13,209; copy number 2: 35,604; copy number 3: 9,873; copy number 4: 409; copy number 6: 42; copy number 7: 341; copy number 8: 196; copy number 9: 104; copy number 10: 26; copy number 16: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QK-A6VC-01A-23D-A34I-01): tumor purity 0.21, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,967,752–22,128,103, 7 genes (within-gene range 0–1): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr11:12,094,008–12,359,144, 1 gene (within-gene range 0–2): MICAL2.
- chr11:12,261,426–12,308,216, 2 genes: AC079329.1, AC025300.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 715 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:89,882,353–117,323,152, 553 genes, copy number 7–9 (broad region; genes not listed).
- chr7:117,332,761–117,428,123, 2 genes, copy number 9: AC002465.1, ASZ1.
- chr8:31,639,222–32,855,666, 1 gene, copy number 16 (within-gene range 1–16): NRG1.
- chr8:32,026,210–38,853,028, 117 genes, copy number 7–16 (within-gene range 1–16) (broad region; genes not listed).
- chr8:55,102,028–55,542,054, 1 gene, copy number 6 (within-gene range 2–6): XKR4.
- chr8:55,449,509–57,392,882, 41 genes, copy number 6: SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10.

Autosomal genes at a single copy (total copy number 1): 13,209. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
